Somatic mutation profile of tumor specimen C3N-03097-02 (aliquot CPT0199050006) from CPTAC case C3N-03097, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen C3N-03097-02: Sample type: Primary Tumor; Tissue type: Tumor; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7bd0b06-b933-463e-af51-871d29036b98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03097-71 (Blood Derived Normal), aliquot CPT0199300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d286c70a-3041-4ba6-b079-5af641c96985

The open-access MAF lists 701 somatic variants for this specimen: 449 protein-altering or splice-affecting, 221 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 407, Silent 221, Nonsense Mutation 30, Intron 18, Splice Site 5, 5'Flank 4, 3'UTR 4, Frame Shift Del 3, Splice Region 3, RNA 3, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 121/364 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: pathogenic / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2554G>A p.G852R | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs104886186, CM960376; ClinVar: pathogenic; called by muse, varscan2
- PAH | c.1199+1G>A p.X400_splice | Splice Site (SNP) | VAF 59/163 reads (36%) | catalogued as rs62509015, CS011056, CS982306; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758303489, CM073403, COSV56389122, COSV56441978; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAR2 | c.473T>C p.F158S | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs1369483625; called by muse, mutect2, varscan2
- AC011455.2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1288258671, COSV99671165; called by muse, mutect2
- AC011462.1 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54195456; called by muse, mutect2, varscan2
- ACSM2B | c.1629+1G>A p.X543_splice | Splice Site (SNP) | VAF 45/177 reads (25%) | catalogued as rs573312260; called by muse, mutect2, varscan2
- ADAMTS18 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765866153; called by muse, mutect2, varscan2
- ADH6 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as rs750527687; called by muse, mutect2, varscan2
- AGO2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55046503; called by muse, mutect2, varscan2
- AHRR | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs762814318; called by muse, mutect2, varscan2
- ANKS1B | c.2482G>A p.E828K (on ENST00000547776 / NM_152788.4; = p.E54K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768871927, COSV60359870; called by muse, mutect2, varscan2
- AP3B1 | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs780402652, COSV54875623; called by muse, mutect2, varscan2
- ARHGAP26 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 124/457 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.968); catalogued as rs771835850; called by muse, mutect2, varscan2
- ARMC4 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 114/368 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs148908705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL3 | c.3880G>C p.A1294P | Missense Mutation (SNP) | VAF 99/397 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV52472623; called by muse, mutect2, varscan2
- ATP6V1A | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs1028311929; called by muse, mutect2, varscan2
- BACH2 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.645); catalogued as rs774175449; called by muse, mutect2, varscan2
- BARHL2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 199/575 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1230062780; called by muse, mutect2, varscan2
- BCORL1 | c.4925G>T p.R1642L | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99499257; called by muse, mutect2, varscan2
- BMP5 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868005204, COSV63701851, COSV63702549; called by muse, mutect2, varscan2
- BRD4 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 132/508 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868727577; called by muse, mutect2, varscan2
- C20orf194 | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 54/533 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV52697545; called by muse, mutect2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 121/521 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CDH17 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV50327538, COSV99218204; called by muse, mutect2, varscan2
- CDH18 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.601); catalogued as COSV56907573; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by mutect2, varscan2
- CELF4 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 48/446 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs1256595342; called by muse, mutect2, varscan2
- CFHR5 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.105); catalogued as COSV56818067; called by muse, mutect2, varscan2
- CIB2 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 99/497 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51949410; called by muse, mutect2, varscan2
- CROCC | c.4499C>T p.P1500L | Missense Mutation (SNP) | VAF 61/618 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs748575001; called by muse, varscan2
- CRYGC | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335843513; called by muse, mutect2, varscan2
- CUX2 | c.4283C>T p.P1428L | Missense Mutation (SNP) | VAF 208/575 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1191248774, COSV55647727; called by muse, mutect2, varscan2
- CYP4F8 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57854235; called by muse, mutect2, varscan2
- DCC | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59120691; called by muse, mutect2, varscan2
- DDX3X | c.1591A>G p.T531A (on ENST00000399959; = p.T532A on NM_001356.5) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67863354; called by muse, mutect2, varscan2
- DHX34 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs771665841, COSV60897133; called by muse, mutect2, varscan2
- DNAH11 | c.6202C>T p.R2068C | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs745332741, COSV60940114; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 48/407 reads (12%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2, varscan2
- DNAH6 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs866262807, COSV52857633; called by muse, mutect2, varscan2
- DNM1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV57852765; called by muse, mutect2, varscan2
- DPYS | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435584205, COSV60908017; called by muse, mutect2
- DSC3 | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs369208762, COSV64571937; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 116/472 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- EBF2 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1037413614; called by muse, mutect2, varscan2
- EEF2K | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 67/465 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV53785388; called by muse, mutect2, varscan2
- EPHA3 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 128/499 reads (26%) | catalogued as COSV60728471; called by muse, mutect2, varscan2
- EPHB1 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 103/397 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs780597750, COSV67662865; called by muse, mutect2, varscan2
- EPHB3 | c.120G>A p.E40= | Splice Region (SNP) | VAF 100/373 reads (27%) | catalogued as rs200708716; called by muse, mutect2, varscan2
- EPS15L1 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1244673161; called by muse, mutect2, varscan2
- ERN2 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772756672; called by muse, mutect2, varscan2
- FAAP100 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 174/662 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1253169932; called by muse, mutect2, varscan2
- FAM71B | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 126/483 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs768102015, COSV57228119; called by muse, mutect2, varscan2
- FLG | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 172/682 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV64237476, COSV64246276; called by muse, mutect2, varscan2
- FRAS1 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs779070461, COSV99348157; called by muse, mutect2, varscan2
- FYB2 | c.387A>C p.K129N | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV100599468; called by muse, mutect2
- GABRG2 | c.811G>A p.D271N (on ENST00000361925 / NM_001375343.1; = p.D231N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as rs773065895, COSV62716280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAL3ST3 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780886516; called by muse, mutect2, varscan2
- GALNT13 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as rs752238590, COSV67232341; called by muse, mutect2, varscan2
- GDF3 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 106/423 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968641196, COSV61713479; called by muse, mutect2, varscan2
- GNL3L | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 107/217 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225592378; called by muse, mutect2, varscan2
- GON4L | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 136/591 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1249987150; called by muse, mutect2, varscan2
- GRIN1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 106/415 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs770981821; called by muse, mutect2, varscan2
- GUCY2C | c.695T>A p.F232Y | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.663); catalogued as COSV99664131; called by muse, mutect2, varscan2
- HCAR2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 103/438 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs200721962, COSV61025849; called by muse, varscan2
- HCLS1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 99/403 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1311160270; called by muse, mutect2, varscan2
- HMGB4 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 102/524 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV53906224, COSV53974767; called by muse, mutect2, varscan2
- HNRNPCL1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 158/622 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100509014; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 78/663 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs767159140, COSV54561841; called by muse, mutect2, varscan2
- HPS4 | c.1802C>T p.T601I | Missense Mutation (SNP) | VAF 110/423 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772632659; called by muse, mutect2, varscan2
- HTR1F | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 117/430 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV60389111; called by muse, mutect2, varscan2
- HTR3B | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 40/314 reads (13%) | catalogued as rs200640080; called by muse, mutect2, varscan2
- IGLV2-8 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 156/664 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs560474360; called by muse, mutect2, varscan2
- IL15RA | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV66092468; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 89/188 reads (47%) | catalogued as rs1475549924, COSV56258619; called by muse, mutect2, varscan2
- INTS2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 114/444 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs774711072; called by muse, mutect2, varscan2
- IPO8 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 93/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759724163, COSV56245190; called by muse, mutect2
- IQGAP2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769166078, COSV57181948; called by muse, mutect2, varscan2
- ITPR2 | c.7169G>A p.R2390Q | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67274152; called by muse, mutect2, varscan2
- JPH2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 67/553 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs772526418, COSV65902531; called by muse, mutect2, varscan2
- KAT6B | c.5072G>A p.G1691E | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773446079; called by muse, mutect2, varscan2
- KCNH1 | c.1825T>C p.Y609H (on ENST00000271751 / NM_172362.3; = p.Y582H on NM_002238.4) | Missense Mutation (SNP) | VAF 66/542 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1300760584; called by muse, mutect2, varscan2
- KCTD2 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 56/406 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV59369907; called by muse, mutect2, varscan2
- KIAA1217 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV56823260; called by muse, mutect2, varscan2
- KIAA1755 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 95/461 reads (21%) | catalogued as rs763933476; called by muse, mutect2, varscan2
- KIF19 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV63430550; called by muse, mutect2, varscan2
- KIF4B | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 149/542 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV70528424; called by muse, mutect2, varscan2
- KRT14 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 173/601 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1253837899; called by muse, mutect2, varscan2
- KRTAP10-5 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 61/798 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781801318; called by muse, mutect2
- LAMA3 | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as rs760352712; called by muse, varscan2
- LILRA5 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 68/563 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV56645106; called by muse, mutect2, varscan2
- LPAR4 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 127/280 reads (45%) | catalogued as COSV101425151; called by muse, mutect2, varscan2
- LPP | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 69/631 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs766568448; called by muse, mutect2, varscan2
- LRR1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 94/310 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs150690979; called by muse, mutect2, varscan2
- LRRN1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253954205, COSV60012923; called by muse, mutect2, varscan2
- MAGEA8 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs782294702; called by muse, mutect2, varscan2
- MAN2B1 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1356568373, COSV55470317; called by muse, mutect2
- MAPK4 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 75/501 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101245603; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs746689191; called by muse, mutect2, varscan2
- MATK | c.1195G>A p.G399R (on ENST00000310132 / NM_139355.3; = p.G400R on NM_002378.4) | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.278); catalogued as rs541647241, COSV100035821; called by muse, mutect2, varscan2
- MEST | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs1554438288; called by muse, mutect2, varscan2
- MRTFA | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 134/550 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs1325050113; called by muse, mutect2, varscan2
- MS4A18 | c.585C>T p.S195= (on ENST00000398983; = p.S197= on NM_001354471.1) | Splice Region (SNP) | VAF 38/202 reads (19%) | catalogued as rs1055088013; called by muse, mutect2, varscan2
- MTFMT | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs370239519; called by muse, mutect2, varscan2
- MTUS1 | c.2560C>T p.H854Y | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs61733690; called by muse, mutect2, varscan2
- MUC16 | c.33832C>T p.P11278S | Missense Mutation (SNP) | VAF 114/365 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); catalogued as rs1415067940, COSV67492883; called by muse, mutect2, varscan2
- MUC16 | c.8132G>A p.G2711E | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV101200144; called by muse, mutect2
- MUC16 | c.6766C>T p.P2256S | Missense Mutation (SNP) | VAF 101/375 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs748883166; called by muse, mutect2, varscan2
- MUC4 | c.5951C>T p.P1984L | Missense Mutation (SNP) | VAF 172/1738 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs1454303352; called by muse, varscan2
- MYH10 | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV52597493; called by muse, mutect2, varscan2
- MYH2 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV55440127; called by muse, mutect2, varscan2
- MYOCD | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100590917; called by muse, mutect2, varscan2
- NEB | c.7390G>A p.D2464N | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs752379641; called by muse, mutect2, varscan2
- NEXMIF | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.084); catalogued as rs927047621, COSV50024189, COSV99279571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN2 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.07); catalogued as rs756356287, COSV57212063; called by muse, mutect2, varscan2
- NLRC3 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 79/537 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs377029072; called by muse, mutect2, varscan2
- NLRP2 | c.1336G>C p.A446P | Missense Mutation (SNP) | VAF 104/727 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs771265449; called by muse, mutect2, varscan2
- NLRP5 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs369349527; called by muse, varscan2
- NOL3 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 89/585 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs768328284; called by muse, mutect2, varscan2
- NOMO2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs774490456; called by muse, mutect2, varscan2
- NOS3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 102/444 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs748582484, COSV52496818; called by muse, mutect2, varscan2
- NOTCH4 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 164/555 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760538818, COSV100900801; called by muse, mutect2, varscan2
- NTRK3 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs143617169; called by muse, varscan2
- NWD1 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 122/484 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99045796; called by muse, mutect2, varscan2
- NYX | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100699427; called by muse, varscan2
- OPRM1 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs755984329; called by muse, mutect2, varscan2
- OPRM1 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 143/458 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs933361818; called by muse, mutect2, varscan2
- OR10A6 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 70/458 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59164741; called by muse, mutect2, varscan2
- OR13C8 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV58610926; called by muse, mutect2, varscan2
- OR14I1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 122/528 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100700433; called by muse, mutect2, varscan2
- OR1L8 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59186059; called by muse, mutect2
- OR2F2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 105/468 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199756492; called by muse, varscan2
- OR2M2 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 141/621 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV62898328; called by muse, mutect2, varscan2
- OR2T3 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 114/1155 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV62083348, COSV62084077; called by muse, mutect2
- OR5C1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 140/584 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV101030629; called by muse, mutect2
- OR8G1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 84/283 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.323); catalogued as COSV100422498; called by muse, mutect2, varscan2
- OSMR | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1353066506, COSV57083648, COSV57091678; called by muse, mutect2, varscan2
- PAPPA | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 120/492 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs768393018, COSV60292481; called by muse, mutect2, varscan2
- PAPPA | c.3053G>A p.G1018E | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60283546; called by muse, mutect2, varscan2
- PCDHA1 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 150/616 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65375867; called by muse, mutect2, varscan2
- PCDHB11 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); catalogued as COSV99504843; called by muse, mutect2, varscan2
- PCDHB8 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 114/1108 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50759980; called by mutect2, varscan2
- PCDHGA5 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 95/443 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1266306756, COSV53976166; called by muse, mutect2, varscan2
- PCDHGB5 | c.2129G>C p.R710P | Missense Mutation (SNP) | VAF 54/448 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV53916725; called by muse, mutect2, varscan2
- PCDHGB6 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs757187051, COSV53941186; called by muse, mutect2, varscan2
- PCLO | c.6673G>A p.E2225K | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV61665165; called by muse, mutect2, varscan2
- PIK3C2G | c.2234G>A p.R745K (on ENST00000676171; = p.R704K on NM_004570.5) | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56832712; called by muse, mutect2, varscan2
- PKD1L2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs748102348, COSV61414240; called by muse, mutect2, varscan2
- PLCB1 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV62068888, COSV62069897; called by muse, mutect2, varscan2
- PLPPR1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100882893; called by muse, mutect2, varscan2
- PLPPR1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260639911, COSV100883368, COSV66458031; called by muse, mutect2, varscan2
- PNMA8B | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 154/550 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs763635836; called by muse, mutect2, varscan2
- POM121L12 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 44/426 reads (10%) | catalogued as COSV68692778; called by muse, mutect2, varscan2
- PROKR1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58137100; called by muse, mutect2, varscan2
- PRR9 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 101/438 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1311277442; called by muse, mutect2, varscan2
- PRR9 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 100/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1029015868; called by muse, mutect2, varscan2
- PRUNE2 | c.5617C>T p.Q1873* | Nonsense Mutation (SNP) | VAF 48/405 reads (12%) | catalogued as COSV65050169; called by muse, mutect2, varscan2
- PSKH2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369930631; called by muse, mutect2, varscan2
- PTGFR | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 118/463 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV66114930; called by muse, mutect2, varscan2
- PZP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 96/353 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs773631099, COSV54355105, COSV54366093; called by muse, mutect2, varscan2
- RAVER2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 98/486 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); catalogued as rs755955641; called by muse, mutect2, varscan2
- RERE | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 60/522 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100555925; called by muse, mutect2, varscan2
- RGS18 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 54/259 reads (21%) | catalogued as COSV66507160; called by muse, mutect2, varscan2
- RPUSD4 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs775753062; called by muse, mutect2, varscan2
- RTL3 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 133/288 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV58183371; called by muse, mutect2, varscan2
- RTN4 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 184/557 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs756006681, COSV100463734; called by muse, mutect2, varscan2
- SCART1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 148/797 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775375030, COSV62987108; called by muse, mutect2, varscan2
- SCN10A | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 124/473 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101479273; called by muse, mutect2, varscan2
- SCRN3 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55808577; called by muse, mutect2, varscan2
- SEL1L2 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1391706433; called by muse, mutect2, varscan2
- SGCZ | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1355052545, COSV101170164; called by muse, mutect2, varscan2
- SIDT2 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs761595296; called by muse, mutect2, varscan2
- SIGLEC5 | c.841T>G p.W281G | Missense Mutation (SNP) | VAF 67/619 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55781324; called by muse, mutect2, varscan2
- SIGLEC6 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1237553594, COSV58431698; called by muse, mutect2, varscan2
- SIPA1L2 | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 123/432 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV53399665; called by muse, mutect2, varscan2
- SIRT7 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs951715118; called by muse, mutect2, varscan2
- SKP1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs1319964859, COSV100104573; called by muse, mutect2, varscan2
- SLC14A2 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 130/497 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1371592735; called by muse, mutect2, varscan2
- SLC16A14 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54617450; called by muse, mutect2, varscan2
- SLC26A4 | c.921G>A p.T307= | Splice Region (SNP) | VAF 25/224 reads (11%) | catalogued as rs765644650, COSV55914256; called by muse, mutect2, varscan2
- SLC27A6 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs761151157; called by muse, mutect2, varscan2
- SLC8A1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559653918, COSV60477042; called by muse, mutect2, varscan2
- SMYD1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs770519021, COSV70225276; called by muse, mutect2, varscan2
- STK31 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as COSV100669091; called by muse, mutect2, varscan2
- STK31 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63453939, COSV63459549; called by muse, mutect2, varscan2
- SULT1C4 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 48/381 reads (13%) | catalogued as rs1473384145; called by muse, mutect2, varscan2
- TAS1R2 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 154/617 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.123); catalogued as COSV64744564; called by muse, mutect2, varscan2
- TAS2R60 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs780926901; called by muse, mutect2, varscan2
- TET2 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as rs780355921, COSV54400669, COSV54425330; called by muse, mutect2, varscan2
- TEX37 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 55/548 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs746814303, COSV100304682; called by muse, mutect2, varscan2
- TGM1 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 146/468 reads (31%) | catalogued as CM154134; called by muse, mutect2, varscan2
- TGM5 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV55011515; called by muse, mutect2, varscan2
- THSD4 | c.1927C>G p.R643G | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV55959700; called by muse, mutect2, varscan2
- TMEM132B | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 94/295 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs758627102, COSV54743905, COSV54747174; called by muse, mutect2, varscan2
- TMEM41A | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs752219515; called by muse, mutect2, varscan2
- TMEM41A | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs755638940; called by muse, mutect2, varscan2
- TNFRSF10A | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.204); catalogued as COSV55325756; called by muse, mutect2, varscan2
- TNR | c.4052G>A p.R1351K | Missense Mutation (SNP) | VAF 94/388 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV54896544; called by muse, mutect2, varscan2
- TRRAP | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 129/558 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62847295; called by muse, mutect2, varscan2
- TTC22 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 83/607 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1344065041; called by muse, mutect2, varscan2
- TUSC3 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101140732, COSV65880512; called by muse, mutect2, varscan2
- TYMP | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 111/487 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as rs1284840530, COSV52689709, COSV99329590; called by muse, mutect2, varscan2
- UNC79 | c.5749G>A p.G1917R (on ENST00000393151 / NM_001346218.2; = p.G1740R on NM_020818.5) | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56415225; called by muse, mutect2, varscan2
- UNC79 | c.5750G>A p.G1917E (on ENST00000393151 / NM_001346218.2; = p.G1740E on NM_020818.5) | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781284690, COSV56400065; called by muse, mutect2, varscan2
- UNC80 | c.6472G>A p.D2158N | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1363311880; called by muse, mutect2, varscan2
- USH2A | c.3920C>T p.S1307L | Missense Mutation (SNP) | VAF 96/488 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as CM054170, COSV56378913; called by muse, mutect2, varscan2
- UTP14C | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 132/388 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs1408555356; called by muse, mutect2
- VCAN | c.8755G>A p.E2919K | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99424805; called by muse, mutect2, varscan2
- VCX | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs374291810, COSV99050230; called by muse, mutect2, varscan2
- VCX3A | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.029); catalogued as rs200714581; called by muse, mutect2, varscan2
- WBP2NL | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 134/656 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1017395618; called by muse, mutect2, varscan2
- WNT6 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 192/671 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs746914545; called by muse, mutect2, varscan2
- XAGE5 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs1376205674, COSV100657823; called by muse, mutect2, varscan2
- YRDC | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs578235508; called by muse, mutect2, varscan2
- Z83844.2 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 163/605 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs1334061084; called by muse, mutect2, varscan2
- ZBTB25 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 57/372 reads (15%) | catalogued as COSV101170744; called by muse, mutect2, varscan2
- ZDBF2 | c.6112G>A p.D2038N | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs866762136, COSV65622204, COSV65624305; called by muse, mutect2, varscan2
- ZKSCAN2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.823); catalogued as rs760122199; called by muse, mutect2, varscan2
- ZNF135 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs200161186, COSV57883575; called by muse, mutect2, varscan2
- ZNF280A | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 143/598 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV100131162; called by muse, mutect2, varscan2
- ZNF318 | c.5615C>T p.S1872L | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV58937875; called by muse, mutect2, varscan2
- ZNF329 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 87/392 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV63773638; called by muse, mutect2, varscan2
- ZNF536 | c.2293C>T p.H765Y | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62827786; called by muse, mutect2
- ZNF536 | c.3704G>A p.S1235N | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.02); catalogued as rs866347483, COSV62829637; called by muse, mutect2, varscan2
- ZNF675 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 27/214 reads (13%) | catalogued as COSV100705082; called by muse, mutect2, varscan2
- ZNF846 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1482556555, COSV67412549; called by muse, mutect2
- ZSCAN1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 161/596 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV56604656; called by muse, mutect2, varscan2
- ABHD16B | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 77/671 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS2 | c.2290+1G>C p.X764_splice | Splice Site (SNP) | VAF 21/438 reads (5%) | called by muse, mutect2
- ADD2 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB1 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 58/373 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- AKAP3 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AKAP8L | c.117T>A p.N39K | Missense Mutation (SNP) | VAF 64/411 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALPK3 | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 144/582 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD30B | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ANKRD36C | c.3639G>T p.K1213N | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- ANKRD66 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- AP5M1 | c.154del p.A54Hfs*34 | Frame Shift Del (DEL) | VAF 98/365 reads (27%) | called by mutect2, pindel, varscan2
- ARID2 | c.5107G>A p.D1703N | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ARMC3 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ASPA | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ASPM | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ATP9A | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- BEND4 | c.1108C>G p.Q370E | Missense Mutation (SNP) | VAF 62/346 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BICRAL | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 35/282 reads (12%) | called by muse, mutect2, varscan2
- BOP1 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRWD1 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- C1orf87 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); called by muse, mutect2
- C20orf194 | c.2176C>G p.H726D | Missense Mutation (SNP) | VAF 52/478 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C2orf16 | c.2589G>A p.M863I | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- C2orf16 | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 107/338 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.586); called by mutect2, varscan2
- CACNA1E | c.4626G>A p.W1542* | Nonsense Mutation (SNP) | VAF 69/312 reads (22%) | called by muse, mutect2, varscan2
- CACNA1S | c.3034A>C p.T1012P | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP3 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 148/423 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CBFA2T3 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC141 | c.2181G>A p.W727* | Nonsense Mutation (SNP) | VAF 43/259 reads (17%) | called by muse, mutect2, varscan2
- CCDC172 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CCDC183 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 48/439 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CCDC88A | c.2537A>G p.E846G | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CD180 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDC27 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP72 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 96/373 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CFAP54 | c.7866G>A p.M2622I | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, varscan2
- CHD2 | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 99/387 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CHST13 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 95/404 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILK1 | c.1697T>A p.F566Y (on ENST00000350082 / NM_001375397.1; = p.F559Y on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CLPTM1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLSTN2 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CNTNAP3 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 90/471 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRK | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRNN | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 190/674 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CSMD1 | c.2855C>T p.P952L (on ENST00000520002; = p.P951L on NM_033225.6) | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNA3 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CUX2 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 86/657 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CX3CL1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 54/444 reads (12%) | called by muse, mutect2, varscan2
- DAP3 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 137/548 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DCAF8L1 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- DGKI | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DLC1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH12 | c.4939C>T p.Q1647* (on ENST00000351747; = p.Q1670* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 104/395 reads (26%) | called by muse, mutect2, varscan2
- DNAJB1 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 13/496 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DOCK2 | c.5155G>A p.D1719N | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK5 | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- DPH2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 122/454 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DPRX | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 96/353 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSEL | c.2199C>G p.N733K | Missense Mutation (SNP) | VAF 63/493 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- EFCAB14 | c.1241T>G p.F414C | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- EGR1 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 136/486 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, varscan2
- EHBP1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK3 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHB6 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 171/846 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERFE | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ERVW-1 | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 103/467 reads (22%) | called by muse, mutect2, varscan2
- F10 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 149/450 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F2RL3 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 102/563 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FAAP100 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 178/666 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- FAM104A | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 152/562 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.23); called by muse, varscan2
- FBN2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGR1A | c.68T>G p.V23G | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FSIP2 | c.2404G>A p.G802R | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- GALC | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 117/345 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- GALNT13 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GDF7 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 67/556 reads (12%) | called by muse, mutect2, varscan2
- GHRHR | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GNG13 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 80/269 reads (30%) | called by muse, mutect2, varscan2
- GPD1 | c.847-6_851del p.X283_splice | Splice Site (DEL) | VAF 22/212 reads (10%) | called by mutect2, pindel
- GPRC5C | c.1012C>T p.L338F (on ENST00000652232; = p.L293F on NM_018653.4) | Missense Mutation (SNP) | VAF 122/622 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GRIA1 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2IRD2B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 67/460 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GTF2IRD2B | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 66/462 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GUCY2F | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HIGD2B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- HOXA3 | c.889T>A p.F297I | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by mutect2, varscan2
- HSF5 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- HTR3C | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- HYDIN | c.13943C>T p.T4648I | Missense Mutation (SNP) | VAF 48/618 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2
- IBA57 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 114/506 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IL17RE | c.1797_1824del p.K600Pfs*42 | Frame Shift Del (DEL) | VAF 98/557 reads (18%) | called by mutect2, pindel, varscan2
- IL31RA | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQGAP3 | c.3745T>C p.F1249L | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IZUMO3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- KCNA5 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 55/507 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNAB1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2
- KCNB2 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 42/358 reads (12%) | called by muse, mutect2, varscan2
- KIAA0930 | c.960_961dup p.K321Rfs*45 (on ENST00000336156 / NM_001009880.2; = p.K326Rfs*45 on NM_015264.2) | Frame Shift Ins (INS) | VAF 95/549 reads (17%) | called by mutect2, pindel, varscan2
- KIAA1671 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 102/511 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIAA2012 | c.1994G>A p.R665K | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.15); called by muse, mutect2, varscan2
- KIF9 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 67/639 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- KLK6 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 60/465 reads (13%) | called by muse, mutect2, varscan2
- KPNA1 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KRTAP5-11 | c.29G>C p.C10S | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, varscan2
- LNX1 | c.986G>A p.G329E (on ENST00000263925 / NM_001126328.3; = p.G233E on NM_032622.2) | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC66 | c.731T>A p.F244Y | Missense Mutation (SNP) | VAF 127/390 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LY75 | c.1526G>A p.R509K | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- LYPD8 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAMDC4 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1LC3C | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 74/302 reads (25%) | called by mutect2, varscan2
- MAP2K5 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MCM8 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 99/401 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED16 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 53/606 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- MIOS | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC1 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 92/354 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOV10L1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 90/386 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MRPS9 | c.830A>T p.K277M | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MS4A18 | c.584C>T p.S195F (on ENST00000398983; = p.S197F on NM_001354471.1) | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTPN | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MXRA5 | c.6469G>A p.D2157N | Missense Mutation (SNP) | VAF 142/318 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYORG | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 135/480 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NEB | c.3421C>T p.H1141Y | Missense Mutation (SNP) | VAF 35/500 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.514); called by muse, mutect2
- NEO1 | c.896T>A p.L299* | Nonsense Mutation (SNP) | VAF 68/302 reads (23%) | called by muse, mutect2, varscan2
- NFATC1 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 88/652 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- NLRP14 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NOTCH4 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 163/553 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPHP3 | c.2079T>G p.S693R | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NPVF | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NR6A1 | c.1326G>A p.M442I (on ENST00000487099 / NM_033334.4; = p.M437I on NM_001489.5) | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NUP214 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OCRL | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- OCSTAMP | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 75/722 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR10T2 | c.887A>C p.E296A | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR1A2 | c.847T>A p.L283I | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.407); called by mutect2, varscan2
- OR1B1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4F5 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 82/507 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- P3H3 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- PALB2 | c.3481T>G p.F1161V | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- PAM | c.2611A>G p.T871A | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- PCDHA4 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 68/416 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCNX2 | c.4507C>A p.Q1503K | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.034); called by mutect2, varscan2
- PGAP1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PGS1 | c.1106C>G p.T369S | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIAS2 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PIM2 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 150/295 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCXD2 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 110/474 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLK1 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA4 | c.4639A>T p.K1547* | Nonsense Mutation (SNP) | VAF 84/332 reads (25%) | called by muse, mutect2, varscan2
- POLI | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- POTEG | c.212G>A p.W71* | Nonsense Mutation (SNP) | VAF 161/888 reads (18%) | called by muse, varscan2
- PP2D1 | c.1888A>C p.T630P | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PP2D1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 90/414 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PPM1H | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 136/453 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PPP1R15A | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 136/561 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRAMEF18 | c.665T>A p.V222E | Missense Mutation (SNP) | VAF 144/1045 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRG4 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 142/701 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PROX1 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 101/491 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PRPS1L1 | c.411T>A p.F137L | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PRRC2B | c.3569G>A p.G1190D | Missense Mutation (SNP) | VAF 86/495 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PSKH2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA1 | c.5854C>T p.P1952S | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBL2 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPS4X | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- RTN2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 103/458 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SDR39U1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.241); called by mutect2, varscan2
- SERPINA5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SESN2 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 51/468 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIGLEC9 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SIRPB1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 123/581 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SLC25A46 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SLC9C2 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SLCO1C1 | c.1659T>A p.Y553* | Nonsense Mutation (SNP) | VAF 53/402 reads (13%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1973G>A p.W658* | Nonsense Mutation (SNP) | VAF 28/239 reads (12%) | called by muse, mutect2, varscan2
- SV2B | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 63/460 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE1 | c.17912C>T p.S5971F (on ENST00000367255 / NM_182961.4; = p.S5900F on NM_033071.3) | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SYNE1 | c.625A>G p.S209G (on ENST00000367255 / NM_182961.4; = p.S216G on NM_033071.3) | Missense Mutation (SNP) | VAF 108/319 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TBX6 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 129/527 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TCEANC | c.466C>T p.P156S (on ENST00000380600 / NM_001297563.2; = p.P186S on NM_152634.4) | Missense Mutation (SNP) | VAF 123/272 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TCEANC | c.467C>T p.P156L (on ENST00000380600 / NM_001297563.2; = p.P186L on NM_152634.4) | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEK | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM2 | c.3725C>G p.A1242G (on ENST00000518659 / NM_001122679.2; = p.A1010G on NM_001080428.3) | Missense Mutation (SNP) | VAF 72/427 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TERF2IP | c.61T>C p.F21L | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, varscan2
- TFAP2D | c.1109T>G p.L370R | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2
- THRAP3 | c.124A>C p.K42Q | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THSD7B | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TIE1 | c.3374A>G p.N1125S | Missense Mutation (SNP) | VAF 87/416 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TM7SF2 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TMC5 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM44 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMF1 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TNFRSF11B | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNRC18 | c.6109G>A p.D2037N | Missense Mutation (SNP) | VAF 73/573 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TOP2A | c.3106T>G p.W1036G | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2
- TOPAZ1 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 111/372 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TRIM24 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM49B | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TRIML1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 149/464 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TRMT44 | c.2044G>A p.V682I | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- TSEN34 | c.656T>A p.L219Q | Missense Mutation (SNP) | VAF 92/688 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- TSHZ2 | c.2980T>C p.F994L | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTN | c.26924T>C p.L8975P (on ENST00000591111; = p.L8048P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/274 reads (23%) | PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UBASH3A | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- UGT1A3 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- UNC80 | c.6473A>T p.D2158V | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- USP20 | c.1136-1G>A p.X379_splice | Splice Site (SNP) | VAF 35/324 reads (11%) | called by muse, mutect2, varscan2
- USP24 | c.7372G>A p.E2458K | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- USP33 | c.397T>A p.L133M | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- UTP14C | c.330A>T p.K110N | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.19); called by muse, mutect2
- VCX3B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.133); called by mutect2, varscan2
- VSIG10 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- XKR9 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- Z82206.1 | c.174del p.K59Rfs*24 | Frame Shift Del (DEL) | VAF 89/432 reads (21%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.1498T>A p.F500I | Missense Mutation (SNP) | VAF 163/359 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFHX4 | c.9911C>T p.P3304L | Missense Mutation (SNP) | VAF 64/425 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZFP30 | c.1339T>A p.F447I | Missense Mutation (SNP) | VAF 43/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF28 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF681 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF831 | c.4897G>T p.E1633* | Nonsense Mutation (SNP) | VAF 80/394 reads (20%) | called by muse, mutect2, varscan2
- ZNF836 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 69/457 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF865 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 82/605 reads (14%) | SIFT tolerated (0.38); called by muse, varscan2
- AADACL4 | c.84C>T p.F28= | Silent (SNP) | VAF 123/528 reads (23%) | called by muse, mutect2, varscan2
- AC138647.1 | c.108C>T p.F36= | Silent (SNP) | VAF 51/307 reads (17%) | called by muse, mutect2, varscan2
- ADARB1 | c.816G>A p.Q272= | Silent (SNP) | VAF 109/375 reads (29%) | called by muse, mutect2, varscan2
- ADD2 | c.111G>A p.R37= | Silent (SNP) | VAF 60/484 reads (12%) | called by muse, mutect2, varscan2
- AGAP1 | c.717C>T p.S239= | Silent (SNP) | VAF 52/389 reads (13%) | catalogued as rs141251996; called by muse, mutect2, varscan2
- AGBL2 | c.2382C>T p.T794= | Silent (SNP) | VAF 95/325 reads (29%) | called by muse, mutect2, varscan2
- AGO4 | c.2340A>G p.E780= | Silent (SNP) | VAF 106/469 reads (23%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2913G>A p.V971= | Silent (SNP) | VAF 153/513 reads (30%) | called by muse, mutect2, varscan2
- APCDD1L | c.1227G>A p.V409= | Silent (SNP) | VAF 138/543 reads (25%) | called by muse, mutect2, varscan2
- ARG1 | c.72G>A p.V24= | Silent (SNP) | VAF 96/299 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1432C>T p.L478= | Silent (SNP) | VAF 57/373 reads (15%) | called by muse, mutect2, varscan2
- ATP10D | c.1608C>T p.S536= | Silent (SNP) | VAF 82/262 reads (31%) | called by muse, varscan2
- ATP1B1 | c.453C>T p.F151= | Silent (SNP) | VAF 107/529 reads (20%) | catalogued as rs547810622; called by muse, mutect2, varscan2
- B4GALNT4 | c.2382C>A p.P794= | Silent (SNP) | VAF 158/526 reads (30%) | catalogued as COSV104396010; called by muse, mutect2, varscan2
- BRD4 | c.1929C>T p.S643= | Silent (SNP) | VAF 130/499 reads (26%) | catalogued as COSV99650352; called by muse, mutect2, varscan2
- BTC | c.240G>A p.G80= | Silent (SNP) | VAF 80/267 reads (30%) | catalogued as COSV67547565; called by muse, mutect2, varscan2
- C1orf158 | c.459C>A p.P153= | Silent (SNP) | VAF 123/442 reads (28%) | called by muse, mutect2, varscan2
- C20orf194 | c.3102C>T p.S1034= | Silent (SNP) | VAF 54/538 reads (10%) | called by muse, mutect2
- C6 | c.2244G>A p.G748= | Silent (SNP) | VAF 44/335 reads (13%) | catalogued as COSV54704890; called by muse, mutect2, varscan2
- C8B | c.294A>G p.E98= | Silent (SNP) | VAF 116/481 reads (24%) | catalogued as COSV64776373; called by muse, varscan2
- CACNG7 | c.588C>T p.S196= | Silent (SNP) | VAF 59/365 reads (16%) | catalogued as rs774720326; called by muse, mutect2, varscan2
- CAND2 | c.2697C>T p.F899= (on ENST00000456430 / NM_001162499.2; = p.F806= on NM_012298.3) | Silent (SNP) | VAF 142/565 reads (25%) | called by muse, mutect2, varscan2
- CBLN4 | c.150G>A p.T50= | Silent (SNP) | VAF 133/598 reads (22%) | catalogued as rs1295945825; called by muse, mutect2, varscan2
- CCDC83 | c.555C>T p.I185= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as COSV99721563; called by muse, mutect2, varscan2
- CD8B | c.204G>A p.E68= | Silent (SNP) | VAF 83/568 reads (15%) | catalogued as rs754692260; called by muse, mutect2, varscan2
- CDH18 | c.2028G>A p.L676= | Silent (SNP) | VAF 55/406 reads (14%) | called by muse, mutect2, varscan2
- CDK6 | c.297A>G p.E99= | Silent (SNP) | VAF 105/453 reads (23%) | catalogued as COSV56009099, COSV99721522; called by muse, mutect2, varscan2
- CELF4 | c.522C>T p.A174= | Silent (SNP) | VAF 48/444 reads (11%) | catalogued as rs1304945234; called by muse, mutect2, varscan2
- CHDH | c.963C>T p.I321= | Silent (SNP) | VAF 66/346 reads (19%) | called by muse, mutect2, varscan2
- CILP | c.2736C>T p.F912= | Silent (SNP) | VAF 64/556 reads (12%) | called by muse, mutect2, varscan2
- CILP | c.1914C>T p.A638= | Silent (SNP) | VAF 120/558 reads (22%) | called by muse, mutect2, varscan2
- COBL | c.378C>T p.T126= | Silent (SNP) | VAF 113/472 reads (24%) | called by muse, mutect2, varscan2
- COL28A1 | c.2562G>A p.Q854= | Silent (SNP) | VAF 118/461 reads (26%) | called by muse, mutect2, varscan2
- COL8A1 | c.126T>C p.P42= | Silent (SNP) | VAF 132/547 reads (24%) | called by muse, mutect2, varscan2
- CSMD2 | c.3252G>A p.R1084= | Silent (SNP) | VAF 121/503 reads (24%) | called by muse, mutect2, varscan2
- CX3CL1 | c.432C>T p.S144= | Silent (SNP) | VAF 53/442 reads (12%) | called by muse, mutect2, varscan2
- CYB5D1 | c.466C>T p.L156= | Silent (SNP) | VAF 31/274 reads (11%) | called by muse, mutect2, varscan2
- CYBB | c.639G>A p.V213= | Silent (SNP) | VAF 99/199 reads (50%) | called by muse, mutect2, varscan2
- CYP2C18 | c.657C>T p.F219= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV53669799; called by muse, mutect2, varscan2
- DALRD3 | c.807C>T p.A269= (on ENST00000341949 / NM_001009996.3; = p.A102= on NM_018114.5) | Silent (SNP) | VAF 48/382 reads (13%) | catalogued as rs1282814646; called by muse, mutect2, varscan2
- DBX2 | c.543C>T p.S181= | Silent (SNP) | VAF 88/286 reads (31%) | catalogued as rs1565581109, COSV100224201; called by muse, mutect2, varscan2
- DCC | c.4317T>C p.L1439= | Silent (SNP) | VAF 104/338 reads (31%) | called by muse, mutect2, varscan2
- DENND2A | c.1587G>A p.L529= | Silent (SNP) | VAF 86/330 reads (26%) | catalogued as rs771998967; called by muse, mutect2, varscan2
- DHX8 | c.1086C>T p.T362= | Silent (SNP) | VAF 94/485 reads (19%) | called by muse, mutect2, varscan2
- DNAH11 | c.2493G>A p.Q831= | Silent (SNP) | VAF 134/565 reads (24%) | called by muse, mutect2, varscan2
- DNAH5 | c.4812C>T p.F1604= | Silent (SNP) | VAF 41/278 reads (15%) | catalogued as COSV54248062, COSV54253190; called by muse, mutect2, varscan2
- DNMBP | c.3837C>T p.S1279= | Silent (SNP) | VAF 95/337 reads (28%) | called by muse, mutect2, varscan2
- DROSHA | c.2524C>T p.L842= | Silent (SNP) | VAF 39/325 reads (12%) | catalogued as rs372932779; called by muse, mutect2, varscan2
- DTX1 | c.657G>A p.L219= | Silent (SNP) | VAF 118/378 reads (31%) | called by muse, mutect2, varscan2
- EEFSEC | c.351C>T p.I117= | Silent (SNP) | VAF 93/370 reads (25%) | catalogued as COSV54620121; called by muse, mutect2, varscan2
- ELFN2 | c.999C>T p.F333= | Silent (SNP) | VAF 107/531 reads (20%) | catalogued as rs1212086696; called by muse, mutect2, varscan2
- ENTHD1 | c.1473G>A p.L491= | Silent (SNP) | VAF 80/321 reads (25%) | called by muse, mutect2, varscan2
- EPHA1 | c.1194G>C p.G398= | Silent (SNP) | VAF 143/596 reads (24%) | catalogued as rs774402556; called by muse, mutect2, varscan2
- EPHB2 | c.999C>T p.S333= | Silent (SNP) | VAF 99/407 reads (24%) | catalogued as COSV65866807; called by muse, mutect2, varscan2
- ERFE | c.840C>T p.D280= | Silent (SNP) | VAF 52/456 reads (11%) | called by muse, mutect2, varscan2
- ERMARD | c.468T>A p.L156= | Silent (SNP) | VAF 84/307 reads (27%) | called by muse, mutect2, varscan2
- ESYT3 | c.354C>T p.V118= | Silent (SNP) | VAF 100/419 reads (24%) | catalogued as rs759769436; called by muse, mutect2, varscan2
- EXOC3L1 | c.369G>A p.R123= | Silent (SNP) | VAF 121/404 reads (30%) | catalogued as rs1160487239; called by muse, mutect2, varscan2
- FAM189B | c.1209C>T p.S403= | Silent (SNP) | VAF 206/823 reads (25%) | called by muse, mutect2, varscan2
- FLG | c.4458G>A p.Q1486= | Silent (SNP) | VAF 70/645 reads (11%) | catalogued as rs755509585; called by muse, mutect2, varscan2
- GAP43 | c.144G>A p.R48= | Silent (SNP) | VAF 101/464 reads (22%) | called by muse, mutect2, varscan2
- GBF1 | c.3378C>T p.F1126= (on ENST00000369983 / NM_001377137.1; = p.F1125= on NM_004193.3) | Silent (SNP) | VAF 109/346 reads (32%) | catalogued as rs374888034; called by muse, mutect2, varscan2
- GBX1 | c.9G>A p.R3= | Silent (SNP) | VAF 50/262 reads (19%) | called by muse, mutect2, varscan2
- GGA2 | c.192C>T p.P64= | Silent (SNP) | VAF 69/374 reads (18%) | called by muse, mutect2, varscan2
- GLI2 | c.4440C>T p.S1480= (on ENST00000361492 / NM_001374353.1; = p.S1497= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/535 reads (12%) | catalogued as rs1403391073; called by muse, mutect2, varscan2
- GON4L | c.120G>A p.K40= | Silent (SNP) | VAF 135/586 reads (23%) | called by muse, mutect2, varscan2
- GRIK5 | c.2860C>T p.L954= | Silent (SNP) | VAF 76/229 reads (33%) | called by muse, mutect2, varscan2
- GRIN1 | c.2598G>A p.K866= | Silent (SNP) | VAF 43/271 reads (16%) | called by muse, mutect2, varscan2
- GRIN2D | c.858G>T p.G286= | Silent (SNP) | VAF 26/690 reads (4%) | called by muse, mutect2
- HADHA | c.1554C>T p.S518= | Silent (SNP) | VAF 64/404 reads (16%) | called by muse, mutect2, varscan2
- HAPLN3 | c.591C>T p.S197= | Silent (SNP) | VAF 174/667 reads (26%) | called by muse, mutect2, varscan2
- HAVCR2 | c.250C>T p.L84= | Silent (SNP) | VAF 47/388 reads (12%) | called by muse, mutect2, varscan2
- HDAC9 | c.2277C>T p.I759= | Silent (SNP) | VAF 109/458 reads (24%) | catalogued as rs1060499865, COSV67775548; ClinVar: likely benign; called by muse, mutect2, varscan2
- HECW1 | c.2238C>T p.F746= | Silent (SNP) | VAF 161/647 reads (25%) | catalogued as rs765972904, COSV67827286; called by muse, mutect2, varscan2
- HIGD2B | c.108G>A p.K36= | Silent (SNP) | VAF 39/310 reads (13%) | called by muse, mutect2, varscan2
- HMCN2 | c.14199C>T p.T4733= | Silent (SNP) | VAF 49/462 reads (11%) | catalogued as rs1304971715; called by muse, mutect2, varscan2
- HPS4 | c.1803C>T p.T601= | Silent (SNP) | VAF 108/420 reads (26%) | called by muse, mutect2, varscan2
- HTR3D | c.180T>C p.S60= | Silent (SNP) | VAF 86/376 reads (23%) | called by muse, mutect2, varscan2
- HYDIN | c.13944C>T p.T4648= | Silent (SNP) | VAF 50/626 reads (8%) | called by muse, mutect2
- IGFN1 | c.354C>T p.L118= | Silent (SNP) | VAF 87/372 reads (23%) | called by muse, mutect2, varscan2
- IGSF1 | c.3531G>A p.K1177= | Silent (SNP) | VAF 151/325 reads (46%) | catalogued as COSV104421378; called by muse, mutect2, varscan2
- IGSF21 | c.513C>T p.I171= | Silent (SNP) | VAF 68/358 reads (19%) | catalogued as rs1168474333, COSV52137478; called by muse, varscan2
- ITGB3 | c.2259C>T p.F753= | Silent (SNP) | VAF 84/399 reads (21%) | catalogued as rs546345692, COSV71384884, COSV71385016; called by muse, mutect2, varscan2
- KANSL1L | c.327G>A p.L109= | Silent (SNP) | VAF 52/336 reads (15%) | called by muse, mutect2, varscan2
- KCND2 | c.534C>A p.P178= | Silent (SNP) | VAF 116/527 reads (22%) | called by muse, mutect2, varscan2
- KCNH8 | c.1479C>T p.F493= | Silent (SNP) | VAF 109/411 reads (27%) | called by muse, mutect2, varscan2
- KCNN1 | c.561C>T p.F187= | Silent (SNP) | VAF 121/568 reads (21%) | catalogued as rs773376258; called by muse, mutect2, varscan2
- KCNS2 | c.1377G>A p.L459= | Silent (SNP) | VAF 47/329 reads (14%) | called by muse, varscan2
- KIF2B | c.1293C>T p.I431= | Silent (SNP) | VAF 130/420 reads (31%) | catalogued as COSV52135251; called by muse, mutect2, varscan2
- KIF5C | c.63G>A p.A21= | Silent (SNP) | VAF 54/343 reads (16%) | called by muse, mutect2, varscan2
- LCA5L | c.1920C>T p.S640= | Silent (SNP) | VAF 91/332 reads (27%) | called by muse, mutect2, varscan2
- LIPJ | c.627C>T p.F209= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as rs751090349, COSV64245154, COSV64245189; called by muse, mutect2, varscan2
- LMO2 | c.351G>A p.L117= (on ENST00000395833 / NM_001142315.2; = p.L186= on NM_005574.4) | Silent (SNP) | VAF 126/365 reads (35%) | catalogued as rs202158823; called by muse, mutect2
- LMTK3 | c.2208C>T p.L736= | Silent (SNP) | VAF 27/215 reads (13%) | called by muse, mutect2, varscan2
- LPP | c.870C>T p.A290= | Silent (SNP) | VAF 68/634 reads (11%) | catalogued as rs761556133; called by muse, mutect2, varscan2
- LRIT3 | c.1764C>T p.T588= | Silent (SNP) | VAF 112/356 reads (31%) | called by muse, mutect2, varscan2
- LRRC45 | c.252C>T p.A84= | Silent (SNP) | VAF 73/446 reads (16%) | called by muse, mutect2, varscan2
- LUZP1 | c.1344A>G p.T448= | Silent (SNP) | VAF 101/411 reads (25%) | called by muse, mutect2, varscan2
- LVRN | c.504C>T p.N168= | Silent (SNP) | VAF 47/370 reads (13%) | catalogued as rs752634994, COSV63497645; called by muse, mutect2, varscan2
- MAGEC3 | c.588C>T p.L196= | Silent (SNP) | VAF 111/238 reads (47%) | catalogued as rs1411566598, COSV71610234; called by muse, mutect2, varscan2
- MAGI1 | c.3519C>T p.I1173= (on ENST00000402939 / NM_001033057.2; = p.I1202= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/358 reads (12%) | catalogued as rs1449140468; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1422C>T p.N474= | Silent (SNP) | VAF 58/305 reads (19%) | catalogued as rs1368370778; called by muse, mutect2, varscan2
- METTL16 | c.309C>T p.L103= | Silent (SNP) | VAF 70/278 reads (25%) | catalogued as rs752332818; called by muse, mutect2, varscan2
- MORN1 | c.651C>T p.I217= | Silent (SNP) | VAF 82/329 reads (25%) | catalogued as rs1409760769; called by muse, mutect2, varscan2
- MPG | c.783G>A p.R261= | Silent (SNP) | VAF 160/587 reads (27%) | called by muse, mutect2, varscan2
- MRM1 | c.717C>T p.P239= | Silent (SNP) | VAF 119/443 reads (27%) | called by muse, mutect2, varscan2
- MROH2A | c.4881G>A p.L1627= | Silent (SNP) | VAF 85/324 reads (26%) | called by muse, mutect2, varscan2
- MROH2B | c.627C>T p.I209= | Silent (SNP) | VAF 41/315 reads (13%) | catalogued as rs769380827, COSV68182314; called by muse, mutect2, varscan2
- MRS2 | c.420G>A p.L140= | Silent (SNP) | VAF 38/124 reads (31%) | called by muse, varscan2
- MSTO1 | c.300G>A p.K100= | Silent (SNP) | VAF 54/265 reads (20%) | called by muse, mutect2, varscan2
- MTMR7 | c.411G>A p.T137= | Silent (SNP) | VAF 44/308 reads (14%) | catalogued as rs140578144; called by muse, varscan2
- MUC16 | c.3306C>T p.F1102= | Silent (SNP) | VAF 100/335 reads (30%) | catalogued as rs765318016, COSV67445229; called by muse, mutect2, varscan2
- MUC17 | c.5343C>A p.T1781= | Silent (SNP) | VAF 60/537 reads (11%) | called by muse, mutect2, varscan2
- MYH2 | c.84G>A p.Q28= | Silent (SNP) | VAF 61/490 reads (12%) | called by muse, mutect2, varscan2
- MYLK3 | c.118C>T p.L40= | Silent (SNP) | VAF 75/478 reads (16%) | called by muse, mutect2, varscan2
- MYRF | c.1317G>A p.E439= (on ENST00000278836 / NM_001127392.3; = p.E430= on NM_013279.4) | Silent (SNP) | VAF 128/350 reads (37%) | catalogued as COSV99039184; called by muse, mutect2, varscan2
- MYT1L | c.1902G>A p.K634= | Silent (SNP) | VAF 43/429 reads (10%) | catalogued as rs1459043245, COSV67726103; called by muse, mutect2, varscan2
- NEB | c.3420C>T p.P1140= | Silent (SNP) | VAF 34/503 reads (7%) | called by muse, mutect2
- NFATC1 | c.174C>T p.L58= | Silent (SNP) | VAF 88/656 reads (13%) | called by muse, mutect2
- NIBAN2 | c.2058C>T p.A686= | Silent (SNP) | VAF 87/631 reads (14%) | catalogued as rs764486451; called by muse, mutect2, varscan2
- NLGN2 | c.993G>A p.R331= | Silent (SNP) | VAF 115/420 reads (27%) | called by muse, mutect2, varscan2
- NLRP4 | c.1257C>T p.L419= | Silent (SNP) | VAF 49/385 reads (13%) | called by muse, mutect2, varscan2
- NOD1 | c.813C>T p.F271= | Silent (SNP) | VAF 65/636 reads (10%) | called by muse, mutect2, varscan2
- NOD2 | c.1263G>A p.K421= | Silent (SNP) | VAF 101/432 reads (23%) | catalogued as rs749142500; called by muse, mutect2, varscan2
- NOL3 | c.426C>T p.S142= | Silent (SNP) | VAF 82/548 reads (15%) | catalogued as rs1183950636; called by muse, varscan2
- NOS1 | c.1920C>T p.I640= | Silent (SNP) | VAF 64/265 reads (24%) | catalogued as rs202177894, COSV100499929, COSV57609344; called by muse, mutect2, varscan2
- NPHP4 | c.2016C>T p.F672= | Silent (SNP) | VAF 86/432 reads (20%) | catalogued as COSV100976982; called by muse, mutect2, varscan2
- NUP210L | c.5079C>T p.I1693= | Silent (SNP) | VAF 121/502 reads (24%) | catalogued as COSV55147802; called by muse, mutect2, varscan2
- NYX | c.516C>T p.R172= | Silent (SNP) | VAF 169/352 reads (48%) | catalogued as rs757923916; called by muse, varscan2
- OGFOD3 | c.264G>A p.V88= | Silent (SNP) | VAF 63/376 reads (17%) | called by muse, mutect2, varscan2
- OPLAH | c.2175C>T p.V725= | Silent (SNP) | VAF 81/464 reads (17%) | catalogued as COSV70677279; called by muse, mutect2, varscan2
- OR13C5 | c.414G>A p.K138= | Silent (SNP) | VAF 58/446 reads (13%) | catalogued as COSV66165292; called by muse, mutect2, varscan2
- OR13C8 | c.606G>A p.S202= | Silent (SNP) | VAF 80/294 reads (27%) | catalogued as rs146773946; called by muse, varscan2
- OR2M4 | c.489C>T p.V163= | Silent (SNP) | VAF 123/480 reads (26%) | catalogued as COSV60708510; called by muse, mutect2, varscan2
- OR4A47 | c.381C>T p.P127= | Silent (SNP) | VAF 60/337 reads (18%) | catalogued as rs776153456; called by muse, mutect2, varscan2
- OR4D6 | c.714C>T p.S238= | Silent (SNP) | VAF 120/421 reads (29%) | called by muse, mutect2, varscan2
- OR5C1 | c.132G>A p.L44= | Silent (SNP) | VAF 138/594 reads (23%) | called by muse, mutect2
- PCDHB11 | c.1845C>T p.F615= | Silent (SNP) | VAF 78/838 reads (9%) | catalogued as COSV100697148; called by muse, mutect2, varscan2
- PCDHGA2 | c.2334G>A p.T778= | Silent (SNP) | VAF 121/547 reads (22%) | catalogued as rs773019891, COSV53906585; called by muse, mutect2, varscan2
- PCED1A | c.558C>T p.L186= | Silent (SNP) | VAF 108/488 reads (22%) | catalogued as rs374829387; called by muse, mutect2, varscan2
- PCSK5 | c.237G>A p.T79= | Silent (SNP) | VAF 44/377 reads (12%) | catalogued as rs200413560, COSV65087490; called by muse, mutect2, varscan2
- PDZRN4 | c.2730C>T p.I910= (on ENST00000402685 / NM_001164595.2; = p.I652= on NM_013377.4) | Silent (SNP) | VAF 65/391 reads (17%) | catalogued as COSV54205947; called by muse, mutect2, varscan2
- PHF21B | c.1572C>T p.V524= | Silent (SNP) | VAF 121/479 reads (25%) | called by muse, mutect2, varscan2
- PI3 | c.24C>T p.I8= | Silent (SNP) | VAF 123/542 reads (23%) | catalogued as rs912430823, COSV54783551; called by muse, mutect2
- PLEK | c.621C>T p.N207= | Silent (SNP) | VAF 45/385 reads (12%) | called by muse, mutect2, varscan2
- PLEKHM3 | c.648T>C p.G216= | Silent (SNP) | VAF 89/366 reads (24%) | called by muse, mutect2, varscan2
- POM121L12 | c.687C>T p.F229= | Silent (SNP) | VAF 144/644 reads (22%) | catalogued as rs377744248, COSV68692454; called by muse, mutect2, varscan2
- POTEC | c.12G>A p.E4= | Silent (SNP) | VAF 86/293 reads (29%) | catalogued as rs1367997342; called by muse, mutect2, varscan2
- PPP2R5D | c.978C>T p.V326= | Silent (SNP) | VAF 44/294 reads (15%) | called by muse, mutect2, varscan2
- PRMT1 | c.609C>T p.I203= | Silent (SNP) | VAF 134/499 reads (27%) | catalogued as rs370260864; called by muse, mutect2, varscan2
- PRRC2B | c.5598C>T p.S1866= | Silent (SNP) | VAF 43/397 reads (11%) | called by muse, mutect2, varscan2
- PSMC2 | c.36C>T p.T12= | Silent (SNP) | VAF 78/413 reads (19%) | called by muse, mutect2, varscan2
- PTMA | c.261G>A p.T87= (on ENST00000341369 / NM_001099285.2; = p.T86= on NM_002823.5) | Silent (SNP) | VAF 99/395 reads (25%) | catalogued as rs764394114, COSV100398499; called by muse, mutect2, varscan2
- PTPRD | c.5409C>T p.F1803= | Silent (SNP) | VAF 53/273 reads (19%) | catalogued as COSV61947776; called by muse, mutect2, varscan2
- RAVER2 | c.870G>A p.Q290= | Silent (SNP) | VAF 98/493 reads (20%) | catalogued as rs750205889; called by muse, mutect2, varscan2
- RBM12 | c.132C>T p.F44= | Silent (SNP) | VAF 108/464 reads (23%) | catalogued as rs762422639; called by muse, mutect2, varscan2
- RBMXL2 | c.471C>T p.V157= | Silent (SNP) | VAF 147/402 reads (37%) | called by muse, mutect2, varscan2
- REEP6 | c.342G>A p.V114= | Silent (SNP) | VAF 86/312 reads (28%) | called by muse, varscan2
- REN | c.1158C>T p.I386= | Silent (SNP) | VAF 110/531 reads (21%) | catalogued as COSV99689574; called by muse, mutect2, varscan2
- RGPD2 | c.48G>A p.Q16= | Silent (SNP) | VAF 66/335 reads (20%) | catalogued as COSV59530709; called by muse, mutect2, varscan2
- RGS3 | c.2619G>A p.Q873= (on ENST00000350696 / NM_001282923.2; = p.Q592= on NM_130795.4) | Silent (SNP) | VAF 190/621 reads (31%) | called by muse, mutect2, varscan2
- RIF1 | c.5731C>T p.L1911= | Silent (SNP) | VAF 40/327 reads (12%) | catalogued as rs779160047; called by muse, mutect2, varscan2
- RPE65 | c.1315T>C p.L439= | Silent (SNP) | VAF 100/352 reads (28%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.990C>T p.Y330= | Silent (SNP) | VAF 34/234 reads (15%) | called by muse, mutect2, varscan2
- RTN2 | c.135G>A p.E45= | Silent (SNP) | VAF 103/457 reads (23%) | catalogued as rs745940640; called by muse, mutect2, varscan2
- RYR1 | c.14487C>T p.S4829= | Silent (SNP) | VAF 64/329 reads (19%) | called by muse, mutect2, varscan2
- SAMD7 | c.567G>A p.G189= | Silent (SNP) | VAF 135/476 reads (28%) | called by muse, mutect2, varscan2
- SAMD9 | c.3969C>T p.F1323= | Silent (SNP) | VAF 96/399 reads (24%) | catalogued as COSV66073186; called by muse, mutect2, varscan2
- SECISBP2 | c.1704T>C p.G568= | Silent (SNP) | VAF 94/406 reads (23%) | called by muse, mutect2, varscan2
- SELENON | c.1434C>T p.I478= | Silent (SNP) | VAF 91/400 reads (23%) | called by muse, mutect2, varscan2
- SERF1B | c.165C>T p.L55= | Silent (SNP) | VAF 62/591 reads (10%) | called by muse, mutect2
- SESN2 | c.1122C>T p.T374= | Silent (SNP) | VAF 51/467 reads (11%) | called by muse, mutect2, varscan2
- SF1 | c.1875C>T p.P625= | Silent (SNP) | VAF 152/442 reads (34%) | catalogued as rs756061823; called by muse, mutect2, varscan2
- SGCZ | c.90G>A p.R30= | Silent (SNP) | VAF 47/347 reads (14%) | catalogued as COSV66009153; called by muse, mutect2, varscan2
- SIGLEC12 | c.663C>T p.L221= (on ENST00000291707 / NM_053003.4; = p.L103= on NM_033329.2) | Silent (SNP) | VAF 125/558 reads (22%) | catalogued as rs774857023, COSV52465619; called by muse, mutect2
- SIGLEC8 | c.1038G>A p.Q346= | Silent (SNP) | VAF 69/262 reads (26%) | called by muse, mutect2, varscan2
- SLC22A5 | c.1291C>T p.L431= | Silent (SNP) | VAF 69/284 reads (24%) | called by muse, mutect2, varscan2
- SLC26A4 | c.387C>T p.I129= | Silent (SNP) | VAF 53/245 reads (22%) | catalogued as CD075550; called by muse, mutect2, varscan2
- SLC41A3 | c.1344T>A p.L448= | Silent (SNP) | VAF 128/540 reads (24%) | called by muse, mutect2, varscan2
- SLC4A2 | c.1347C>T p.S449= | Silent (SNP) | VAF 157/655 reads (24%) | catalogued as rs866399396; called by muse, mutect2, varscan2
- SLC5A1 | c.1497T>A p.R499= | Silent (SNP) | VAF 78/407 reads (19%) | called by muse, mutect2, varscan2
- SLC6A19 | c.1386C>T p.I462= | Silent (SNP) | VAF 79/331 reads (24%) | called by muse, mutect2, varscan2
- SLC6A6 | c.1302C>T p.F434= | Silent (SNP) | VAF 76/420 reads (18%) | catalogued as rs751612848; called by muse, mutect2, varscan2
- SMARCA4 | c.2334C>T p.A778= | Silent (SNP) | VAF 110/396 reads (28%) | catalogued as rs757358465; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMTNL2 | c.1113G>A p.V371= (on ENST00000389313 / NM_001114974.2; = p.V227= on NM_198501.3) | Silent (SNP) | VAF 45/271 reads (17%) | catalogued as COSV58808172; called by muse, mutect2, varscan2
- SNF8 | c.75G>A p.G25= | Silent (SNP) | VAF 38/379 reads (10%) | called by muse, mutect2, varscan2
- SPEM2 | c.1350G>A p.R450= | Silent (SNP) | VAF 80/507 reads (16%) | catalogued as COSV100424468, COSV61603148; called by muse, mutect2, varscan2
- SPEM3 | c.411G>A p.R137= | Silent (SNP) | VAF 58/440 reads (13%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2451C>T p.F817= | Silent (SNP) | VAF 109/497 reads (22%) | catalogued as rs756131356; called by muse, mutect2, varscan2
- SRCAP | c.141C>G p.S47= | Silent (SNP) | VAF 71/565 reads (13%) | called by muse, mutect2, varscan2
- STYXL1 | c.582C>T p.S194= | Silent (SNP) | VAF 58/258 reads (22%) | catalogued as COSV50392377; called by muse, mutect2, varscan2
- SZT2 | c.1851G>A p.L617= | Silent (SNP) | VAF 119/471 reads (25%) | catalogued as COSV100987088; called by muse, mutect2, varscan2
- TGM6 | c.1746C>T p.I582= | Silent (SNP) | VAF 129/463 reads (28%) | called by muse, mutect2, varscan2
- THRAP3 | c.123G>A p.R41= | Silent (SNP) | VAF 84/372 reads (23%) | called by muse, mutect2, varscan2
- TLN2 | c.5700G>A p.Q1900= | Silent (SNP) | VAF 137/552 reads (25%) | called by muse, mutect2, varscan2
- TMEM163 | c.744G>A p.A248= | Silent (SNP) | VAF 102/416 reads (25%) | catalogued as rs147914319; called by muse, mutect2, varscan2
- TNRC6C | c.3018C>T p.I1006= | Silent (SNP) | VAF 90/463 reads (19%) | catalogued as rs1255953200; called by muse, mutect2, varscan2
- TRIO | c.5892C>T p.S1964= | Silent (SNP) | VAF 47/323 reads (15%) | called by muse, mutect2, varscan2
- TSHZ1 | c.2157C>T p.L719= (on ENST00000580243 / NM_001308210.2; = p.L674= on NM_005786.6) | Silent (SNP) | VAF 73/507 reads (14%) | catalogued as COSV59014965; called by muse, mutect2, varscan2
- TSSK1B | c.789C>T p.I263= | Silent (SNP) | VAF 63/558 reads (11%) | catalogued as rs568511670, COSV66815216; called by muse, mutect2, varscan2
- TTC3 | c.2979C>T p.F993= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as COSV100696033, COSV61285136; called by muse, mutect2, varscan2
- TTN | c.31158G>A p.K10386= (on ENST00000591111; = p.K9459= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/193 reads (28%) | called by muse, mutect2, varscan2
- UBE2T | c.303C>T p.S101= | Silent (SNP) | VAF 78/342 reads (23%) | called by muse, mutect2, varscan2
- UGT1A6 | c.579C>T p.P193= | Silent (SNP) | VAF 80/608 reads (13%) | called by muse, mutect2
- UGT2B15 | c.1164G>A p.G388= | Silent (SNP) | VAF 66/641 reads (10%) | catalogued as COSV57733762; called by muse, mutect2
- UGT2B17 | c.1164G>A p.G388= | Silent (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- UNC80 | c.9090C>T p.G3030= | Silent (SNP) | VAF 92/358 reads (26%) | called by muse, mutect2, varscan2
- UNK | c.474C>T p.S158= | Silent (SNP) | VAF 66/402 reads (16%) | called by muse, mutect2, varscan2
- VPS8 | c.3075T>A p.S1025= (on ENST00000625842 / NM_001349294.1; = p.S1023= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/326 reads (24%) | called by muse, varscan2
- VPS9D1 | c.1602G>A p.R534= | Silent (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- WDCP | c.417C>T p.F139= | Silent (SNP) | VAF 46/419 reads (11%) | catalogued as COSV99722027; called by muse, mutect2, varscan2
- WNK2 | c.2391G>A p.P797= | Silent (SNP) | VAF 46/407 reads (11%) | catalogued as rs1262209111; called by muse, mutect2, varscan2
- XPC | c.2796C>T p.S932= | Silent (SNP) | VAF 60/370 reads (16%) | called by muse, mutect2
- ZCWPW1 | c.144G>A p.E48= | Silent (SNP) | VAF 90/595 reads (15%) | called by muse, mutect2, varscan2
- ZCWPW2 | c.465C>T p.F155= | Silent (SNP) | VAF 70/339 reads (21%) | catalogued as rs373422090, COSV67499059; called by muse, mutect2, varscan2
- ZNF385D | c.306G>A p.T102= | Silent (SNP) | VAF 84/399 reads (21%) | catalogued as rs150360612, COSV55752511; called by muse, mutect2, varscan2
- ZNF585B | c.1926C>A p.A642= | Silent (SNP) | VAF 57/544 reads (10%) | called by muse, mutect2, varscan2
- ZNF679 | c.783T>A p.I261= | Silent (SNP) | VAF 81/407 reads (20%) | called by muse, mutect2, varscan2
- ZNF717 | c.2103C>T p.S701= | Silent (SNP) | VAF 72/702 reads (10%) | called by muse, mutect2
- ZNRF4 | c.1110G>A p.R370= | Silent (SNP) | VAF 32/600 reads (5%) | catalogued as COSV55775036; called by muse, mutect2
- ZP3 | c.1102C>T p.L368= (on ENST00000394857 / NM_001110354.2; = p.L317= on NM_007155.6) | Silent (SNP) | VAF 85/444 reads (19%) | called by muse, mutect2, varscan2
- AC008505.1 | n.5371G>A | RNA (SNP) | VAF 49/347 reads (14%) | catalogued as rs1042480510; called by muse, mutect2, varscan2
- AC092070.2 | n.821C>T | RNA (SNP) | VAF 59/431 reads (14%) | called by muse, mutect2, varscan2
- AC092070.2 | n.822A>G | RNA (SNP) | VAF 59/429 reads (14%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58842015 C>G | 5'Flank (SNP) | VAF 129/491 reads (26%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849516 A>G | 5'Flank (SNP) | VAF 108/208 reads (52%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.*59G>A | 3'UTR (SNP) | VAF 50/376 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.*281C>T | 3'UTR (SNP) | VAF 16/262 reads (6%) | catalogued as COSV100150261; called by muse, mutect2
- C8orf34 | c.1549+3281C>T | Intron (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- CLEC19A | chr16:19307545 G>A | 3'Flank (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- CSNK1D | chr17:82239993 G>A | 3'Flank (SNP) | VAF 94/451 reads (21%) | catalogued as rs972921274; called by muse, mutect2, varscan2
- DDHD1 | c.1846+2529C>G | Intron (SNP) | VAF 51/195 reads (26%) | catalogued as COSV60358901; called by muse, mutect2, varscan2
- DLGAP4 | c.2011-320C>T | Intron (SNP) | VAF 90/357 reads (25%) | called by muse, varscan2
- DNAH14 | c.3052-23053C>A | Intron (SNP) | VAF 53/255 reads (21%) | catalogued as rs1316487717; called by muse, mutect2, varscan2
- FAM184A | c.1815+303G>A | Intron (SNP) | VAF 72/220 reads (33%) | catalogued as rs1375566766; called by muse, varscan2
- IQCC | c.42+10C>T | Intron (SNP) | VAF 90/403 reads (22%) | catalogued as rs1449965995; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22485G>A | Intron (SNP) | VAF 92/342 reads (27%) | catalogued as COSV67486079; called by muse, varscan2
- KCNQ1 | c.1393+24005C>T | Intron (SNP) | VAF 59/201 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-35057A>C | Intron (SNP) | VAF 50/285 reads (18%) | catalogued as rs948377445; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+19772C>T | Intron (SNP) | VAF 97/257 reads (38%) | called by muse, mutect2, varscan2
- MKNK2 | c.*1806C>T | 3'UTR (SNP) | VAF 34/241 reads (14%) | catalogued as rs1460680294; called by muse, mutect2, varscan2
- MLIP | c.613-11889C>T | Intron (SNP) | VAF 118/392 reads (30%) | catalogued as COSV99230446; called by muse, mutect2, varscan2
- PDXK | c.142+2932C>T | Intron (SNP) | VAF 82/293 reads (28%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157681 C>T | 5'Flank (SNP) | VAF 50/340 reads (15%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49594554 C>T | 5'Flank (SNP) | VAF 101/589 reads (17%) | catalogued as rs201023608; called by muse, mutect2, varscan2
- RPGRIP1L | c.3835+51C>T | Intron (SNP) | VAF 126/431 reads (29%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12769G>A | Intron (SNP) | VAF 79/335 reads (24%) | catalogued as COSV67451912; called by muse, mutect2, varscan2
- SUN1 | c.658+13C>T | Intron (SNP) | VAF 75/348 reads (22%) | called by muse, mutect2, varscan2
- TBXA2R | c.*656T>C | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- ZIC4 | c.-16+969G>A | Intron (SNP) | VAF 97/412 reads (24%) | called by muse, mutect2, varscan2
- ZNF655 | c.136+3348C>T | Intron (SNP) | VAF 71/313 reads (23%) | catalogued as COSV53158916; called by muse, mutect2, varscan2
- ZNF783 | c.802+3351C>T | Intron (SNP) | VAF 195/753 reads (26%) | catalogued as rs1563200015; called by muse, mutect2, varscan2
